CCDI case PBCCUB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/071e125d-8719-4a9b-b9c3-54347758fd02

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Malignant tumor, small cell type: ICD-O-3 morphology code: 8002/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.7 years (3,916 days).

Biospecimens (3 samples)
- Sample 0DOXFZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DOXGM: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DOXGW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
